CCDI case PBCADN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/3d83c9ee-015d-4361-8413-b7300362d31f

Demographics
Sex at birth: female; Race: white.

Biospecimens (3 samples)
- Sample 0DM8U6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM8VY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DM8W2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
